Somatic mutation profile of tumor specimen TARGET-10-PAPEJN-09A (aliquot TARGET-10-PAPEJN-09A-01D) from TARGET case TARGET-10-PAPEJN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,129 days).
Specimen TARGET-10-PAPEJN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2ead10a-d516-47a2-86eb-e5c2bff34aef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPEJN-14A (Bone Marrow Normal), aliquot TARGET-10-PAPEJN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf897ae6-dc25-4d98-a15c-ac9795456a2b

The open-access MAF lists 29 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, Intron 4, RNA 2, Splice Region 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BPTF | c.4672G>C p.V1558L | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV58831428, COSV58842071; called by muse, mutect2, varscan2
- CIT | c.3301C>T p.L1101F | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.722); catalogued as COSV55859933, COSV55870820; called by muse, mutect2, varscan2
- ECPAS | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV52191681; called by muse, varscan2
- HARS1 | c.685A>G p.S229G | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV56905525; called by muse, mutect2, varscan2
- MET | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 127/251 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV59257156; called by muse, mutect2, varscan2
- MYO15A | c.7982C>T p.S2661L | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.285); catalogued as CM115299; called by muse, mutect2
- SCYL3 | c.2017A>C p.M673L (on ENST00000367770; = p.M619L on NM_020423.7) | Missense Mutation (SNP) | VAF 85/222 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53676652; called by muse, mutect2, varscan2
- URGCP | c.1763C>T p.T588M (on ENST00000453200 / NM_001077663.3; = p.T579M on NM_017920.4) | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs537964326, COSV56245139; called by muse, mutect2, varscan2
- AASDH | c.1895C>T p.P632L | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CMTM2 | c.582_588del p.D195Vfs*61 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | called by mutect2, pindel*
- IGHV3-30 | chr14:106335074 del ACTGTGTCT | Missense Mutation (DEL) | VAF 21/115 reads (18%) | called by pindel, varscan2
- MERTK | c.1146C>T p.A382= | Splice Region (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2
- NR2F1 | c.473G>C p.R158P | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- PAGE5 | c.196C>G p.Q66E | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.298); called by muse, mutect2
- PLEKHG3 | c.2380G>C p.E794Q (on ENST00000394691; = p.E850Q on NM_001308147.2) | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC13A1 | c.1123C>A p.L375I | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BTAF1 | c.2007C>A p.T669= | Silent (SNP) | VAF 19/86 reads (22%) | called by muse, mutect2, varscan2
- CATSPERE | c.1386C>T p.N462= | Silent (SNP) | VAF 65/148 reads (44%) | called by muse, mutect2, varscan2
- FAT3 | c.7086G>A p.L2362= | Silent (SNP) | VAF 34/124 reads (27%) | called by muse, mutect2, varscan2
- SCRIB | c.3645C>T p.I1215= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs145515611; called by muse, mutect2, varscan2
- SPG21 | c.138C>T p.L46= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as rs1229037004; called by muse, mutect2, varscan2
- TRPC4 | c.1671G>A p.Q557= | Silent (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- CYP4Z2P | n.500G>T | RNA (SNP) | VAF 50/97 reads (52%) | called by muse, mutect2, varscan2
- DST | c.21198+44C>T | Intron (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- KIR3DP1 | n.578C>G | RNA (SNP) | VAF 42/174 reads (24%) | called by muse, mutect2, varscan2
- NRP2 | c.2440+693C>G | Intron (SNP) | VAF 8/120 reads (7%) | catalogued as rs1434135204; called by muse, mutect2
- SBF1 | c.3827-140G>T | Intron (SNP) | VAF 14/23 reads (61%) | called by muse, mutect2, varscan2
- TTN | c.10360+5305G>C | Intron (SNP) | VAF 27/127 reads (21%) | catalogued as rs866939633; called by muse, mutect2, varscan2
- UBE4A | c.*2650G>C | 3'UTR (SNP) | VAF 28/118 reads (24%) | called by muse, mutect2, varscan2
